Somatic mutation profile of tumor specimen TCGA-13-2060-01A (aliquot TCGA-13-2060-01A-01W-0799-08) from TCGA case TCGA-13-2060, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 51.0 years (18,635 days).
Specimen TCGA-13-2060-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab77bb20-3d11-4ad4-97b5-304b62c4cf70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-2060-10A (Blood Derived Normal), aliquot TCGA-13-2060-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05e31f09-c438-4715-b19f-a64671ee5918

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Nonsense Mutation 4, Frame Shift Del 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 156/228 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.3253C>T p.R1085W | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199943026, COSV55947837; called by muse, mutect2, varscan2
- ACCSL | c.1684T>G p.L562V | Missense Mutation (SNP) | VAF 125/747 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV66580822; called by muse, mutect2, varscan2
- AGBL2 | c.1726C>A p.R576S | Missense Mutation (SNP) | VAF 74/490 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV54091124; called by muse, mutect2, varscan2
- APMAP | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV54173311; called by muse, mutect2, varscan2
- ATF7IP | c.1798C>A p.Q600K | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.166); catalogued as COSV99661300; called by muse, mutect2
- ATP6V0A2 | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1416379430, COSV57748497; called by muse, mutect2, varscan2
- BRD2 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66372945; called by muse, mutect2
- CCT4 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 7/158 reads (4%) | catalogued as COSV101075090; called by muse, mutect2
- CD200R1 | c.179G>C p.C60S (on ENST00000471858 / NM_170780.3; = p.C83S on NM_138806.4) | Missense Mutation (SNP) | VAF 140/802 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV99866842; called by muse, mutect2, varscan2
- CNBD1 | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV72916825; called by muse, mutect2, varscan2
- CNTNAP2 | c.2993G>T p.G998V | Missense Mutation (SNP) | VAF 62/622 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62163674; called by muse, mutect2
- CNTNAP5 | c.3824A>C p.K1275T | Missense Mutation (SNP) | VAF 81/593 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV70480830; called by muse, mutect2, varscan2
- DCC | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 14/130 reads (11%) | catalogued as COSV59088081; called by muse, mutect2, varscan2
- DMGDH | c.239A>G p.E80G | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369030617; called by muse, mutect2, varscan2
- DVL3 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.979); catalogued as rs372800702, COSV57455549; called by muse, mutect2, varscan2
- HTR2C | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV52206434; called by muse, mutect2, varscan2
- KIF18B | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 110/157 reads (70%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV59272195; called by muse, mutect2, varscan2
- LRPPRC | c.3312T>A p.D1104E | Missense Mutation (SNP) | VAF 16/548 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV99580101; called by muse, mutect2
- LRRC27 | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100689693; called by muse, mutect2, varscan2
- MACF1 | c.7160G>A p.C2387Y | Missense Mutation (SNP) | VAF 183/579 reads (32%) | catalogued as rs1001676410, COSV57115088; called by muse, mutect2, varscan2
- MDN1 | c.5453A>G p.H1818R | Missense Mutation (SNP) | VAF 136/218 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV101020880; called by muse, mutect2, varscan2
- MRPL14 | c.175C>A p.H59N | Missense Mutation (SNP) | VAF 120/881 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV64394495; called by muse, mutect2, varscan2
- MRPS35 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV99317331; called by muse, mutect2
- MUC7 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 177/954 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.437); catalogued as COSV59217830; called by muse, mutect2, varscan2
- NRXN1 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 64/360 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV100456706, COSV58444619; called by muse, varscan2
- ONECUT2 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1349085016, COSV72153056; called by muse, mutect2, varscan2
- PODN | c.833G>A p.R278H (on ENST00000395871; = p.R230H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs1333307112, COSV57012401, COSV57014174; called by muse, mutect2, varscan2
- RBFOX1 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.065); catalogued as COSV60953593; called by muse, mutect2, varscan2
- RFXANK | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.544); catalogued as rs1479307125, COSV57393010; called by muse, mutect2, varscan2
- RRAGD | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 66/107 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1393177336, COSV100784634, COSV63268809; called by muse, mutect2, varscan2
- TBC1D2 | c.547C>G p.P183A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.366); catalogued as rs1384725476, COSV59784104; called by muse, mutect2, varscan2
- TICRR | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV51540064; called by muse, mutect2, varscan2
- TOGARAM2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 107/217 reads (49%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs996854246, COSV65420710; called by muse, mutect2, varscan2
- TRAF7 | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58213642; called by muse, mutect2, varscan2
- UGT2A1 | c.125A>C p.E42A | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV99683961; called by muse, varscan2
- USP14 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV99863864; called by muse, mutect2
- UXS1 | c.298G>C p.V100L | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV51676447; called by muse, mutect2, varscan2
- WDR70 | c.761A>T p.K254M | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54270361; called by muse, mutect2, varscan2
- ZNF585B | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as rs758906949, COSV57215029; called by muse, mutect2, varscan2
- CNTLN | c.3617del p.K1206Sfs*15 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- OR4F6 | c.758_765del p.P253Lfs*13 | Frame Shift Del (DEL) | VAF 85/543 reads (16%) | called by mutect2, pindel, varscan2
- PROX1 | c.1147_1149del p.F383del | In Frame Del (DEL) | VAF 34/374 reads (9%) | called by mutect2, pindel
- TMEM81 | c.189_190del p.C63* | Nonsense Mutation (DEL) | VAF 34/248 reads (14%) | called by pindel, varscan2
- AAAS | c.1485C>T p.S495= | Silent (SNP) | VAF 24/185 reads (13%) | catalogued as COSV52932583; called by muse, mutect2, varscan2
- ASMTL | c.1284C>T p.F428= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs758484632, COSV101187705; called by muse, mutect2
- ATP11A | c.2634G>A p.R878= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV52109260; called by muse, mutect2, varscan2
- BEND7 | c.177G>A p.P59= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs149156418; called by muse, mutect2, varscan2
- CPN2 | c.1050G>C p.T350= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV60470043; called by muse, mutect2, varscan2
- FAM135B | c.1455T>C p.N485= | Silent (SNP) | VAF 62/330 reads (19%) | catalogued as COSV52716325; called by muse, mutect2, varscan2
- FBN2 | c.2883G>A p.V961= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV52505071; called by muse, mutect2, varscan2
- GJB2 | c.243G>A p.L81= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV101241473; called by muse, mutect2
- PPP1R3B | c.495G>A p.T165= | Silent (SNP) | VAF 14/306 reads (5%) | catalogued as rs138887555; called by muse, mutect2
- PRR23B | c.276C>T p.L92= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as rs778934989, COSV100271962; called by muse, mutect2
- STAM | c.1572C>T p.S524= | Silent (SNP) | VAF 46/380 reads (12%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.864G>A p.P288= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1360412471, COSV61326680; ClinVar: likely benign; called by muse, mutect2, varscan2
- QRICH2 | c.-1C>T | 5'UTR (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99428880, COSV99429665; called by mutect2, varscan2
